Gene-level copy-number profile of tumor specimen ALCH-B2NN-TTP1-A from ALCHEMIST case ALCH-B2NN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.1 years (25,590 days).
Specimen ALCH-B2NN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59990646-4367-4858-a459-8290100349f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/31fb4d11-d8f1-40fe-a988-4b46766f06f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 8,812; copy number 2: 48,070; copy number 3: 1,613; copy number 4: 98; copy number 5: 55; copy number 6: 86; copy number 7: 31; copy number 8: 13; copy number 9: 1; copy number 10: 1; copy number 11: 8; copy number 14: 2; copy number 43: 2.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,916,123–241,999,098, 4 genes: RPL23AP20, BECN2, CFL1P4, MAP1LC3C.
- chr3:141,936,707–141,938,547, 1 gene: AC112504.1.
- chr5:57,120,796–57,169,209, 2 genes: AC034244.2, Y_RNA.
- chr5:69,875,271–69,920,867, 2 genes: GUSBP13, AC131392.1.
- chr5:70,094,659–70,128,434, 1 gene: NAIPP2.
- chr5:134,081,914–134,082,040, 1 gene: AC008608.1.
- chr6:39,188,971–39,229,475, 1 gene: KCNK5.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,642,383–61,789,426, 4 genes: Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:61,861,625–61,866,965, 3 genes: AL391987.2, AL391987.1, AL391987.4.
- chr9:93,951,627–93,955,355, 1 gene: BARX1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr13:19,349,137–19,407,962, 2 genes: PARP4P2, CCNQP3.
- chr13:20,921,664–20,962,195, 4 genes: CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54.
- chr13:28,107,431–28,107,877, 1 gene: CHCHD2P8.
- chr14:92,905,697–92,907,482, 1 gene: LINC02287.
- chr15:25,182,385–25,250,940, 38 genes (within-gene range 0–2): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:64,701,248–64,775,589, 3 genes (within-gene range 0–2): AC100830.1, RBPMS2, MIR1272.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:47,004,513–47,035,385, 2 genes: AC018845.1, AC018845.2.
- chr17:142,789–386,254, 5 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:50,834,650–50,842,353, 2 genes: WFIKKN2, AC091062.1.
- chr19:5,847,467–5,870,540, 2 genes (within-gene range 0–1): AC024592.2, FUT5.
- chr19:33,795,933–33,815,763, 1 gene: KCTD15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,708,931–39,487,177, 19 genes, copy number 8–11: HSPA5P1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8.
- chr1:39,522,280–40,240,921, 28 genes, copy number 7 (within-gene range 4–7): PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P.
- chr2:87,301,658–87,302,251, 1 gene, copy number 5: DBF4P3.
- chr5:69,560,191–69,624,049, 2 genes, copy number 14: GTF2H2C, NAIPP3.
- chr5:70,415,352–70,448,015, 1 gene, copy number 9: GTF2H2B.
- chr7:89,754,620–94,834,447, 86 genes, copy number 6 (broad region; genes not listed).
- chr8:37,326,575–38,468,834, 49 genes, copy number 5: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr9:61,868,727–61,887,084, 2 genes, copy number 11: AL391987.3, Y_RNA.
- chr14:90,820,064–91,060,641, 2 genes, copy number 5 (within-gene range 1–5): LINC02321, RPS6KA5.
- chr16:560,394–584,109, 4 genes, copy number 7–10: PRR35, PIGQ, NHLRC4, Z98883.1.
- chr16:680,224–692,554, 4 genes, copy number 5–43 (within-gene range 2–43): STUB1, JMJD8, WDR24, Z92544.1.
- chr20:48,406,777–48,410,716, 1 gene, copy number 5: AL137078.2.

Autosomal genes at a single copy (total copy number 1): 5,984. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
